Somatic mutation profile of tumor specimen TCGA-BT-A0S7-01A (aliquot TCGA-BT-A0S7-01A-11D-A10S-08) from TCGA case TCGA-BT-A0S7, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 75.4 years (27,533 days).
Specimen TCGA-BT-A0S7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cdb5800a-1bd9-49c9-9d81-2d31f76f25d8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BT-A0S7-10A (Blood Derived Normal), aliquot TCGA-BT-A0S7-10A-01D-A10S-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ee7461c-128e-45e9-adb8-213962a6ddcd

The open-access MAF lists 44 somatic variants for this specimen: 33 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 10, Nonsense Mutation 4, Frame Shift Del 2, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 9/25 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913482, CM950469, COSV53390662; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AKAP6 | c.142T>A p.S48T | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.024); catalogued as COSV55216475; called by muse, mutect2, varscan2
- AL645922.1 | c.374C>T p.S125L | Missense Mutation (SNP) | VAF 68/157 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs753059312, COSV54960912; called by muse, mutect2, varscan2
- AMY2B | c.915C>A p.D305E | Missense Mutation (SNP) | VAF 130/380 reads (34%) | SIFT tolerated (0.54); PolyPhen benign (0.055); catalogued as COSV63715597; called by muse, mutect2, varscan2
- BRF1 | c.1405G>A p.V469M | Missense Mutation (SNP) | VAF 59/204 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.322); catalogued as rs587665642, COSV59267023, COSV59274483; called by muse, mutect2, varscan2
- C19orf44 | c.663G>T p.L221F | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV55612537; called by muse, mutect2, varscan2
- CSMD1 | c.4526A>G p.Y1509C (on ENST00000520002; = p.Y1508C on NM_033225.6) | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1161740501; called by muse, mutect2, varscan2
- CSMD3 | c.2992A>T p.I998F (on ENST00000297405 / NM_001363185.1; = p.I894F on NM_052900.3) | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV52202165; called by muse, mutect2, varscan2
- CWH43 | c.1687A>T p.I563F | Missense Mutation (SNP) | VAF 64/310 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.656); catalogued as COSV56939607; called by muse, mutect2, varscan2
- DLX6 | c.484G>A p.G162R | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50294494; called by muse, mutect2, varscan2
- FGG | c.569G>A p.S190N | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV60195619; called by muse, mutect2, varscan2
- GABRB2 | c.1372C>T p.R458* (on ENST00000274547; = p.R420* on NM_000813.3) | Nonsense Mutation (SNP) | VAF 44/106 reads (42%) | catalogued as COSV50925183; called by muse, mutect2, varscan2
- HMCN1 | c.15854A>G p.Y5285C | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs568752943, COSV54906866; called by muse, mutect2, varscan2
- HSF1 | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 68/189 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1343030281, COSV68821724; called by muse, mutect2, varscan2
- INPP4B | c.744G>A p.W248* | Nonsense Mutation (SNP) | VAF 16/52 reads (31%) | catalogued as COSV99525563; called by muse, mutect2, varscan2
- INPP4B | c.743G>C p.W248S | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53728736; called by muse, mutect2, varscan2
- KIAA0319L | c.1780+1G>C p.X594_splice | Splice Site (SNP) | VAF 20/131 reads (15%) | catalogued as COSV57846525; called by muse, mutect2, varscan2
- LRIF1 | c.493G>A p.V165I | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.372); catalogued as COSV63897483; called by muse, mutect2, varscan2
- MRPS36 | c.227T>C p.I76T | Missense Mutation (SNP) | VAF 80/166 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.127); catalogued as rs747561861, COSV56508077; called by muse, mutect2, varscan2
- MTHFD2 | c.115G>T p.V39F | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV51201502; called by muse, mutect2, varscan2
- MUC16 | c.36046G>A p.E12016K | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV67471751; called by muse, varscan2
- NRXN1 | c.1040G>A p.G347E | Missense Mutation (SNP) | VAF 47/149 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100453793, COSV58459204; called by muse, mutect2, varscan2
- PCDHAC2 | c.549G>T p.Q183H | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.924); catalogued as COSV53853168; called by muse, mutect2, varscan2
- PRAMEF10 | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as rs1224202796; called by mutect2, varscan2
- PTPRT | c.3353A>C p.E1118A | Missense Mutation (SNP) | VAF 78/280 reads (28%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.85); catalogued as COSV61987052; called by muse, mutect2, varscan2
- RASSF8 | c.340C>A p.P114T | Missense Mutation (SNP) | VAF 41/161 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.104); catalogued as COSV51453805; called by muse, mutect2, varscan2
- RIPOR3 | c.2188C>T p.Q730* | Nonsense Mutation (SNP) | VAF 14/262 reads (5%) | catalogued as rs1365166495, COSV99246802; called by muse, mutect2
- SCN2A | c.5227A>G p.K1743E | Missense Mutation (SNP) | VAF 80/332 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.626); catalogued as COSV51844041; called by muse, mutect2, varscan2
- THSD4 | c.1801C>T p.R601* | Nonsense Mutation (SNP) | VAF 57/113 reads (50%) | catalogued as rs373897660; called by muse, mutect2, varscan2
- VWA7 | c.2018A>G p.E673G | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.121); catalogued as COSV65173425; called by muse, mutect2, varscan2
- KDM6A | c.654+1del | Frame Shift Del (DEL) | VAF 20/50 reads (40%) | called by mutect2, pindel, varscan2
- MRM1 | c.16_46del p.T6Sfs*20 | Frame Shift Del (DEL) | VAF 27/139 reads (19%) | called by mutect2, pindel
- OBSCN | c.4493G>A p.R1498K | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (0.56); PolyPhen benign (0.322); called by muse, mutect2
- ABCC6 | c.903G>A p.K301= | Silent (SNP) | VAF 30/94 reads (32%) | catalogued as COSV52744592; called by muse, mutect2, varscan2
- AKT3 | c.1410A>G p.Q470= | Silent (SNP) | VAF 25/51 reads (49%) | catalogued as rs1353565167, COSV55619078; called by muse, mutect2, varscan2
- CCDC144A | c.48G>A p.P16= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV61403591; called by muse, varscan2
- CSMD3 | c.2682A>T p.P894= (on ENST00000297405 / NM_001363185.1; = p.P790= on NM_052900.3) | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV52202180; called by muse, mutect2, varscan2
- KRT73 | c.228C>T p.G76= | Silent (SNP) | VAF 82/263 reads (31%) | catalogued as COSV59839688; called by muse, mutect2, varscan2
- MMRN1 | c.2586G>A p.L862= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV53338333; called by muse, mutect2, varscan2
- NLRP12 | c.102C>T p.T34= | Silent (SNP) | VAF 56/156 reads (36%) | catalogued as rs199600685, COSV60748829; called by muse, varscan2
- RSBN1 | c.2083T>C p.L695= | Silent (SNP) | VAF 17/158 reads (11%) | catalogued as COSV54732749; called by muse, mutect2, varscan2
- USP35 | c.2949G>T p.P983= | Silent (SNP) | VAF 25/162 reads (15%) | catalogued as rs370959438, COSV60868508; called by muse, mutect2, varscan2
- WDR90 | c.1308G>A p.R436= | Silent (SNP) | VAF 53/115 reads (46%) | catalogued as COSV53470949; called by muse, mutect2, varscan2
- SUPT3H | c.-83A>G | 5'UTR (SNP) | VAF 49/143 reads (34%) | catalogued as rs780628100, COSV60941066; called by muse, mutect2, varscan2
